Gene-level copy-number profile of tumor specimen TCGA-DX-AB2X-01A from TCGA case TCGA-DX-AB2X, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 73.2 years (26,736 days).
Specimen TCGA-DX-AB2X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.64eb6928-a008-4cf1-9dc9-b5b7825cbf6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95ae1e88-e9ef-451e-9338-04702f02c2aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 3,409; copy number 2: 28,991; copy number 3: 15,333; copy number 4: 8,281; copy number 5: 1,239; copy number 6: 694; copy number 7: 1,421; copy number 8: 62; copy number 9: 164; copy number 11: 4; copy number 12: 70; copy number 14: 4; copy number 19: 9; copy number 25: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2X-01A-11D-A386-01): tumor purity 0.8, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:176,207,648–176,447,919, 6 genes (within-gene range 0–2): AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1.
- chr4:161,378,953–162,164,004, 2 genes (within-gene range 0–2): AC104793.1, FSTL5.
- chr4:162,322,188–162,323,907, 1 gene: MTHFD2P4.
- chr9:20,331,446–25,089,151, 85 genes (broad region; genes not listed).
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,684 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–154,351,304, 273 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr1:160,485,030–161,422,424, 53 genes, copy number 5: SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P.
- chr1:161,406,068–161,411,802, 2 genes, copy number 5: AL592295.1, AL592295.2.
- chr2:78,088,729–90,235,370, 276 genes, copy number 6 (broad region; genes not listed).
- chr3:84,638,405–90,261,708, 47 genes, copy number 7–25: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr7:76,818,377–82,443,777, 72 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:89,882,353–97,872,542, 128 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:97,870,167–97,870,289, 1 gene, copy number 5: AC005326.1.
- chr7:102,699,228–106,770,207, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:106,781,600–106,781,715, 1 gene, copy number 5: RNA5SP236.
- chr7:117,710,651–124,033,067, 67 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:125,344,969–139,544,985, 279 genes, copy number 5–6 (broad region; genes not listed).
- chr7:143,047,213–150,861,504, 187 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–7 (broad region; genes not listed).
- chr9:25,579,657–43,045,120, 433 genes, copy number 5–9 (broad region; genes not listed).
- chr12:13,437,942–13,982,002, 1 gene, copy number 5 (within-gene range 4–5): GRIN2B.
- chr12:13,526,854–30,695,869, 263 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,475. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
